HCMI case HCM-EXPT-1203-C19 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/e037ecb6-6680-4758-aa56-8daf451bf396

Demographics
Sex at birth: male; Days to birth: -15,888 days (43.5 years before the index date).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Classification of tumor: primary; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Synchronous malignancy: No; Sites of involvement: Liver; Uicc clinical stage: Stage IVA; Uicc pathologic m: M1; Uicc pathologic n: NX; Uicc pathologic stage: Stage IVA; Uicc pathologic t: TX; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Liver; Classification of tumor: metastasis.

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-EXPT-1203-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
